TCGA case TCGA-DG-A2KK — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri; Tissue source site: Ontario Institute for Cancer Research. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8dbcb17d-0396-4faa-9b32-8e2566424bff

Demographics
Sex at birth: female; Country of residence at enrollment: Canada; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 51.6 years (18,834 days); Year of diagnosis: 2007; Method of diagnosis: Biopsy; AJCC pathologic T: T1b1; AJCC pathologic N: N1; AJCC pathologic M: M0; FIGO stage: Stage IIIB; FIGO staging edition year: 1995; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph nodes positive: 2; Lymph nodes tested: 28; Lymphatic invasion present: Yes.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 116 days; Days to treatment end: 156 days; Treatment dose: 4,500 cGy; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 121 days; Days to treatment end: 149 days.

Follow-up (11 entries)
- Days to follow up: 1,544 days (4.2 years); Disease response: Tumor Free.
- Imaging type: MRI; Imaging result: Negative; Imaging findings: Bladder Involvement; Timepoint: Preoperative.
- Imaging type: MRI; Imaging result: Negative; Imaging findings: Parametrium Involvement; Timepoint: Preoperative.
- ECOG performance status: 0; Timepoint: Follow-up.
- Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Parametrium Involvement; Timepoint: Preoperative.
- Imaging type: MRI; Timepoint: Preoperative.
- Imaging type: MRI; Imaging result: Positive; Imaging findings: Pelvic Lymph Node Involvement; Timepoint: Preoperative.
- Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Bladder Involvement; Timepoint: Preoperative.
- Imaging type: CT Scan; Imaging result: Positive; Imaging findings: Pelvic Lymph Node Involvement; Timepoint: Preoperative.
- Imaging type: CT Scan; Timepoint: Preoperative.
- Follow-up contact recording only the day: day 2,496.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.
- Timepoint category: Initial Diagnosis; Weight: 64 kg; Height: 157 cm; BMI: 26.
- Timepoint category: Prior to Diagnosis; Hysterectomy type: Radical Hysterectomy.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 25; Tobacco smoking quit year: 2007; Age at onset: 27.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DG-A2KK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 280 mg.
  Slide TCGA-DG-A2KK-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 25; Percent lymphocyte infiltration: 60; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 10.
- Sample TCGA-DG-A2KK-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DG-A2KK-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: Tumor free; Total pregnancy count: 0; Tobacco smoking history indicator: 4; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Margins involved hysterectomy: Other Location, specify; Other involved margins: Not involved; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymphovascular invasion: Present; Corpus involvement: Absent; New tumor event diagnosis indicator: No.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).
- Diagnostic mri result outcomes: Lymph nodes supraclavicular: Bladder Absent; Lymph nodes supraclavicular: Parametrium Absent; Lymph nodes supraclavicular: Pelvic Nodes Present.
- Diagnostic ct result outcomes: Ct scan preop results: Bladder Absent; Ct scan preop results: Parametrium Absent; Ct scan preop results: Pelvic Nodes Present.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Performance status timing: Pre-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Follow-up form 1, Treatment, Radiation therapy info: Radiation therapy xrt type: External beam radiation.
- Follow-up form 1, Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent fractions total: 5.
- Follow-up form 2: Lost to follow-up: No; Performance status other timing: Endocrinology and Metabolism Clinical Note; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response.
- Follow-up form 2, Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent course: Once weekly; Chemo concurrent fractions total: 5.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,496 days; disease-specific survival: no event (censored), 2,496 days; disease-free interval: no event (censored), 2,496 days; progression-free interval: no event (censored), 2,496 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DG-A2KK-01A-11D-A17U-01): tumor purity 0.84, ploidy 1.99, whole-genome doublings 0.
